Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A7U5, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A7U5-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Thyroid, total thyroidectomy

Tumor histologic type: Papillary thyroid carcinoma, usual variant

Tumor size: 2.4 cm (gross measurement)

Tumor focality & laterality: Unifocal, right

Tumor capsule: Not applicable

Extent of invasion:

Capsular Invasion: Not applicable

Lymphovascular invasion: Not identified

Blood vascular invasion: Present

Extra thyroidal extension: Not identified

ICD O-3
Carcinoma, papillary NOS 8260.13
Site: Thyroid NOS C73.9
9/5/16/14

Surgical margins: Positive, transected over a distance of 9 mm at the black inked posterior margin (A4). Isthmus and anterior margins are negative.

Status of thyroid gland away from tumor: Severe lymphocytic thyroiditis, with follicle formation

Lymph nodes: Three negative lymph nodes are identified in this specimen (0/3)

Size of largest metastasis (greatest dimension): Not applicable

Extracapsular (perinodal) extension: Not applicable

AJCC Pathologic TNM Stage: pT2 pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph node, right level 6, regional dissection

- No metastatic carcinoma in 5 lymph nodes (0/5)

- Benign parathyroid tissue also present

[page 2 of 2]
Clinical History:

year-old female with FNA positive for malignancy, favor papillary thyroid carcinoma.

Gross Description:

Specimen A is received in a formalin-filled container labeled with the patient's name and total thyroid and is a 36.2 gram, thyroid. The specimen arrives with one suture in place designated right. The right lobe measures 7.1 cm superior to inferior x 3.4 cm medial to lateral x 2.5 cm anterior to posterior and the left lobe measures 4.9 cm superior to inferior x 2.3 cm medial to lateral x 2.3 cm anterior to posterior and the isthmus measures 2.9 x 0.8 x 0.3 cm. The specimen is inked as follows: anterior/blue, posterior/black, and isthmus/yellow. Tumor is given to tissue procurement. The thyroid gland is sectioned from superior to inferior. The cut surface reveals a 2.4 x 2.4 x 1.6 cm well-circumscribed white/tan mass centered in the right lobe. The center of the mass is significant for soft hemorrhagic material. The uninvolved thyroid gland is red/brown and firm. There are no other focal nodules or lesions. The mass grossly abuts the blue and black inked margins, but does not appear to extend beyond the capsule.

Block Summary:

A1-A4 - Representative sections of mass (A1 shows closest approach to blue and black inked margins)

A5 - Uninvolved thyroid, left lobe

A6 - Uninvolved thyroid, right lobe

Specimen B is received in a formalin filled container labeled with the patient's name and "level 6 nodes right" and is a 2.1 x 1.2 x 0.6 cm aggregate of yellow lobulated fat. The specimen is palpated and two lymph node candidates are identified measuring 0.6 x 0.5 x 0.5 cm and 0.5 x 0.3 x 0.3 cm.

Block Summary:

B1 - Two lymph node candidates

B2 - Remainder of fat, submitted entirely,

Reviewed Initials:	W 9/24/13	9/24/13

Source: NCI Genomic Data Commons file 54edbc12-08af-4cfc-aab4-c69b6bd69d18 (TCGA-DE-A7U5.D66CF219-B082-4DC3-81B9-F0BC68C31844.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).